ALCHEMIST case ALCH-B2UU — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/1154bdfb-0ab4-40fa-b95f-dd26ae54d1fb

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 60.2 years (21,987 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-B2UU-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-B2UU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-B2UU-TTP1-A-1-0-S2: Section location: Top; Percent tumor cells: 49; Percent tumor nuclei: 63; Percent normal cells: 29; Percent necrosis: 0; Percent stromal cells: 22; Percent lymphocyte infiltration: 11; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
